Somatic mutation profile of tumor specimen TCGA-A6-5656-01A (aliquot TCGA-A6-5656-01A-21D-A270-10) from TCGA case TCGA-A6-5656, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 74.4 years (27,184 days).
Specimen TCGA-A6-5656-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb902d4-1356-433b-8a8e-cf0a93a20cbb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5656-10A (Blood Derived Normal), aliquot TCGA-A6-5656-10A-01D-A270-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f7c5021-49a4-4daa-a326-0b260586efb5

The open-access MAF lists 114 somatic variants for this specimen: 83 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 28, Nonsense Mutation 4, Splice Region 4, Intron 2, In Frame Del 2, Frame Shift Del 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.2624C>T p.T875M (on ENST00000303395 / NM_001202435.3; = p.T864M on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 96/186 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs121918623, CM000569, CM096132, COSV57669847; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 36/48 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1336401643, COSV60916667; called by muse, mutect2, varscan2
- ADAM32 | c.1080C>A p.S360R | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101165455, COSV65952405; called by muse, mutect2, varscan2
- AFAP1L1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs371511486; called by muse, mutect2, varscan2
- ANKRD30A | c.691G>A p.V231I (on ENST00000611781; = p.V175I on NM_052997.2) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as rs200565471, COSV64616844; called by muse, mutect2, varscan2
- APC | c.4314del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 32/110 reads (29%) | catalogued as COSV57354045, COSV57378825; called by mutect2, pindel, varscan2
- ARHGAP31 | c.1508G>A p.S503N | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV99957482; called by muse, mutect2, varscan2
- ATAD2B | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99478178; called by muse, mutect2, varscan2
- ATP12A | c.2735A>C p.D912A | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV99518147; called by muse, mutect2, varscan2
- B3GALT2 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs769360180, COSV66464407; called by muse, mutect2, varscan2
- CABS1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs758926757, COSV56733074; called by muse, mutect2, varscan2
- CENPF | c.6599T>C p.V2200A | Missense Mutation (SNP) | VAF 104/250 reads (42%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV65277509; called by muse, mutect2, varscan2
- CHAT | c.1441C>T p.R481W | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs751583653, COSV60324985, COSV60328624; called by muse, mutect2, varscan2
- CHST15 | c.1609C>T p.R537W | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs774519865, COSV60565153; called by muse, mutect2, varscan2
- CNTROB | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 24/36 reads (67%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV58050786; called by muse, mutect2, varscan2
- COL5A3 | c.4291C>T p.P1431S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370896010; called by muse, mutect2, varscan2
- CRB1 | c.701T>C p.L234S | Missense Mutation (SNP) | VAF 59/140 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100959171; called by muse, mutect2, varscan2
- DBF4B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs139442134; called by muse, mutect2, varscan2
- DCDC1 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as rs369097377, COSV60833095; called by muse, mutect2, varscan2
- DCX | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 106/121 reads (88%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as rs1305044719, COSV57573151; called by muse, mutect2, varscan2
- F10 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV65021670; called by muse, mutect2, varscan2
- F8 | c.3870dup p.G1291Rfs*29 | Frame Shift Ins (INS) | VAF 46/102 reads (45%) | catalogued as rs1426645898; called by mutect2, varscan2
- FAM83C | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs748263316, COSV65583935; called by muse, mutect2, varscan2
- FAM83E | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs577301127, COSV99572364; called by muse, mutect2, varscan2
- GALNT6 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.685); catalogued as rs769886850, COSV62542698; called by muse, mutect2, varscan2
- GAPDHS | c.66G>A p.P22= | Splice Region (SNP) | VAF 17/27 reads (63%) | catalogued as rs925809724, COSV99722860; called by muse, mutect2, varscan2
- GIPC3 | c.591C>T p.F197= | Splice Region (SNP) | VAF 28/63 reads (44%) | catalogued as rs759536524, COSV59260296; called by muse, mutect2, varscan2
- GRID1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs771100097, COSV60044117; called by muse, mutect2, varscan2
- GUCY2C | c.2390A>G p.N797S | Missense Mutation (SNP) | VAF 5/122 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV99663969; called by muse, mutect2
- HAVCR2 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs147605860; called by muse, mutect2, varscan2
- HECW1 | c.4373C>T p.A1458V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV67839253; called by muse, mutect2, varscan2
- IARS2 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759787338, COSV56961947; called by muse, varscan2
- ILDR2 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201864196, COSV54831468; called by muse, mutect2, varscan2
- ITPR1 | c.2188G>A p.V730I (on ENST00000354582; = p.V715I on NM_002222.7) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as rs370701686; called by muse, mutect2, varscan2
- KCNA5 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.017); catalogued as COSV99364072; called by muse, mutect2, varscan2
- KCNG4 | c.759C>T p.G253= | Splice Region (SNP) | VAF 35/113 reads (31%) | catalogued as rs770454941, COSV57585619; called by muse, mutect2, varscan2
- KLHL30 | c.93G>C p.K31N | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59977562; called by muse, mutect2, varscan2
- KRT77 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as rs774353164, COSV59238663; called by muse, mutect2, varscan2
- KRT85 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs370478744; called by muse, mutect2, varscan2
- LOXL4 | c.382G>A p.V128I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs921568799, COSV99583869; called by muse, mutect2, varscan2
- LRCH4 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs769364186, COSV59644063; called by muse, mutect2, varscan2
- LRRC14B | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as rs368280607; called by muse, mutect2, varscan2
- MED19 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.347); catalogued as COSV54709271; called by mutect2, varscan2
- NEDD4L | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.118); catalogued as COSV56849999; called by muse, mutect2, varscan2
- OR5M8 | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 56/81 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59117700; called by muse, mutect2, varscan2
- OR5T2 | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV57589665, COSV57590384; called by muse, mutect2, varscan2
- PCDH15 | c.5015C>A p.S1672Y | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.733); catalogued as COSV100225164; called by muse, mutect2, varscan2
- PCDH15 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.519); catalogued as COSV57364103; called by muse, mutect2, varscan2
- PCDHGB4 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.603); catalogued as rs748559328, COSV53895525; called by muse, mutect2, varscan2
- PCDHGB4 | c.1616C>T p.A539V | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV54001285; called by muse, mutect2, varscan2
- PHACTR3 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.804); catalogued as COSV100732967; called by muse, mutect2, varscan2
- PI4K2B | c.1109C>G p.A370G | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53512460; called by muse, mutect2, varscan2
- PIK3C2B | c.2057G>A p.W686* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100916187; called by muse, mutect2, varscan2
- PLEKHA8 | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV51653757; called by muse, mutect2, varscan2
- POU6F2 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV101302791; called by muse, mutect2, varscan2
- PRSS54 | c.185C>G p.S62C | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99541688; called by muse, mutect2, varscan2
- RXFP3 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1225974660, COSV57503985; called by muse, mutect2, varscan2
- RYR1 | c.10520C>T p.T3507M | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371839408; called by muse, mutect2, varscan2
- SERPIND1 | c.1189T>A p.F397I | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53140133; called by muse, mutect2, varscan2
- SIN3B | c.3448C>T p.R1150C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs546578699, COSV99931921; called by muse, mutect2, varscan2
- SLC15A1 | c.21+1G>A p.X7_splice | Splice Site (SNP) | VAF 169/300 reads (56%) | catalogued as rs374661720; called by muse, mutect2, varscan2
- SLC35G3 | c.136G>C p.G46R | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99269009; called by muse, mutect2
- SLC37A4 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417623185, COSV58155952; called by muse, mutect2, varscan2
- SP100 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 62/92 reads (67%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs766779368, COSV50975085; called by muse, mutect2, varscan2
- SP8 | c.1360G>A p.G454S (on ENST00000361443 / NM_198956.4; = p.G472S on NM_182700.6) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1188466733, COSV63866641; called by muse, mutect2, varscan2
- STOX2 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs369084419; called by muse, mutect2, varscan2
- TBCCD1 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs552386653, COSV58661931; called by muse, mutect2, varscan2
- TBX3 | c.821C>G p.P274R (on ENST00000257566 / NM_016569.4; = p.P254R on NM_005996.4) | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57472188, COSV57474198; called by muse, mutect2, varscan2
- TCHP | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 89/220 reads (40%) | catalogued as COSV100452643, COSV57166180; called by muse, mutect2, varscan2
- THBS2 | c.3370A>C p.R1124= | Splice Region (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100827996; called by muse, mutect2, varscan2
- THEG | c.859G>A p.V287M | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs372037486; called by muse, mutect2, varscan2
- TIMD4 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs773468118, COSV50858004; called by muse, mutect2, varscan2
- TLCD3B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.045); catalogued as rs933771891, COSV54227812; called by muse, mutect2, varscan2
- TMEM163 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.05); catalogued as rs755523021, COSV56110820; called by muse, mutect2, varscan2
- TNS1 | c.3913G>A p.G1305R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.862); catalogued as rs202059695, COSV50690570, COSV50697046; called by muse, mutect2, varscan2
- TNXB | c.8779G>A p.G2927R (on ENST00000647633; = p.G2680R on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs759066378, COSV64485348; called by muse, mutect2, varscan2
- TSHZ3 | c.2444C>T p.P815L | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs766793830, COSV53669970; called by muse, varscan2
- TTN | c.54926G>A p.R18309Q (on ENST00000591111; = p.R10885Q on NM_003319.4) | Missense Mutation (SNP) | VAF 124/192 reads (65%) | PolyPhen probably damaging (0.947); catalogued as rs374914334; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VSTM2L | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 110/153 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as rs1377938011, COSV65096259; called by muse, mutect2, varscan2
- ZNF227 | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 120/340 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100480540; called by muse, varscan2
- EIF3A | c.384_386del p.L129del | In Frame Del (DEL) | VAF 27/74 reads (36%) | called by mutect2, pindel, varscan2
- RELCH | c.2001_2003del p.I667del | In Frame Del (DEL) | VAF 82/117 reads (70%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.1254C>T p.H418= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs758041605, COSV99202823; ClinVar: likely benign; called by muse, mutect2, varscan2
- ADGRD1 | c.90G>A p.S30= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs748431281, COSV55442071; called by muse, mutect2, varscan2
- C12orf57 | c.168C>T p.P56= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs143343192, COSV57547346, COSV99980783; called by muse, mutect2, varscan2
- CCDC54 | c.453G>A p.T151= | Silent (SNP) | VAF 82/210 reads (39%) | catalogued as rs142151683; called by muse, mutect2, varscan2
- CELSR3 | c.8481C>T p.T2827= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs766138738, COSV99374421; called by muse, mutect2, varscan2
- COL20A1 | c.2853C>T p.A951= | Silent (SNP) | VAF 87/119 reads (73%) | catalogued as rs746587840, COSV58924015; called by muse, mutect2, varscan2
- EMILIN3 | c.1431C>T p.L477= | Silent (SNP) | VAF 101/132 reads (77%) | catalogued as rs140838664; called by muse, mutect2, varscan2
- GCM2 | c.444G>A p.A148= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs542569618, COSV65275559; called by muse, mutect2, varscan2
- HMCN1 | c.10902A>G p.L3634= | Silent (SNP) | VAF 6/91 reads (7%) | catalogued as COSV99633238; called by muse, mutect2
- KCNK13 | c.744C>T p.N248= | Silent (SNP) | VAF 39/52 reads (75%) | catalogued as rs574638305, COSV56411938; called by muse, mutect2, varscan2
- KCNMA1 | c.537C>A p.V179= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99698815; called by muse, mutect2
- LCE3E | c.237C>T p.G79= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs540273209, COSV64232081; called by muse, mutect2, varscan2
- MACF1 | c.17790C>T p.D5930= (on ENST00000372915; = p.D3975= on NM_012090.5) | Silent (SNP) | VAF 27/80 reads (34%) | catalogued as rs766713562, COSV57135287; called by muse, mutect2, varscan2
- NAPRT | c.252G>T p.L84= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV99435243; called by muse, mutect2, varscan2
- OR10J3 | c.972G>A p.A324= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs201786076, COSV100171731; called by muse, mutect2, varscan2
- OR4B1 | c.756T>C p.A252= | Silent (SNP) | VAF 33/52 reads (63%) | catalogued as COSV58883536; called by muse, mutect2, varscan2
- OS9 | c.114G>A p.E38= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV57784149; called by muse, mutect2, varscan2
- PCDHA2 | c.1767C>T p.H589= | Silent (SNP) | VAF 79/186 reads (42%) | catalogued as rs782740005, COSV65369794; called by muse, mutect2, varscan2
- PCDHB3 | c.183G>A p.A61= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as COSV50564453; called by muse, mutect2
- PEX13 | c.561T>A p.T187= | Silent (SNP) | VAF 76/189 reads (40%) | catalogued as COSV54371029; called by muse, mutect2, varscan2
- PRF1 | c.363G>A p.A121= | Silent (SNP) | VAF 44/100 reads (44%) | catalogued as rs146358730; called by muse, mutect2, varscan2
- RASGRF1 | c.852C>T p.D284= | Silent (SNP) | VAF 30/80 reads (38%) | catalogued as rs754755775, COSV69181725; called by muse, mutect2, varscan2
- RRM1 | c.993T>C p.A331= | Silent (SNP) | VAF 43/124 reads (35%) | catalogued as rs750572935, COSV100331403; called by muse, mutect2, varscan2
- SIM1 | c.1623G>A p.S541= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs760045551, COSV53492414; called by muse, mutect2, varscan2
- TPP1 | c.1437A>G p.P479= | Silent (SNP) | VAF 30/82 reads (37%) | catalogued as COSV100196550; called by muse, mutect2, varscan2
- TPRX1 | c.912G>A p.P304= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs775098024, COSV59116827; called by muse, mutect2, varscan2
- ZNF431 | c.609T>C p.P203= | Silent (SNP) | VAF 80/196 reads (41%) | catalogued as COSV60674608; called by muse, mutect2, varscan2
- ZNF497 | c.633G>A p.T211= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV54050720; called by muse, mutect2, varscan2
- ACACA | c.339-14357G>C | Intron (SNP) | VAF 14/240 reads (6%) | catalogued as rs777706096; called by muse, mutect2
- KDELR2 | c.*117A>G | 3'UTR (SNP) | VAF 99/164 reads (60%) | catalogued as COSV51727386; called by muse, mutect2, varscan2
- PIK3R1 | c.917-1526A>G | Intron (SNP) | VAF 79/210 reads (38%) | catalogued as COSV99148973; called by muse, mutect2, varscan2
